Gene-level copy-number profile of tumor specimen C3L-02041-02 from CPTAC case C3L-02041, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.8 years (18,904 days).
Specimen C3L-02041-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b156fa59-7e88-4690-86a9-009d9f707684.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02041-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/90b86073-ba41-4a69-be53-de5903b65527

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 805; copy number 3: 3,023; copy number 4: 12,109; copy number 5: 19,295; copy number 6: 19,530; copy number 7: 3,400; copy number 8: 86; copy number 9: 18; copy number 10: 50; copy number 12: 4; copy number 16: 9; copy number 17: 25; copy number 26: 1; copy number 50: 4; copy number 51: 3; copy number 52: 4; copy number 54: 10; copy number 56: 23; copy number 58: 1; copy number 62: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 81 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:11,351,823–11,501,041, 4 genes, copy number 52 (within-gene range 5–52): PRB1, PRB2, AC078950.1, HIGD1AP8.
- chr12:20,361,732–20,370,262, 1 gene, copy number 62 (within-gene range 5–62): AC129102.1.
- chr12:57,747,727–57,756,013, 1 gene, copy number 56 (within-gene range 4–56): CDK4.
- chr12:57,755,103–57,818,704, 10 genes, copy number 56: MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4.
- chr12:64,452,090–64,710,513, 12 genes, copy number 56 (within-gene range 5–56): TBK1, AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1.
- chr12:68,746,125–68,793,964, 1 gene, copy number 54: SLC35E3.
- chr12:75,391,089–75,432,688, 1 gene, copy number 58: GLIPR1L2.
- chr12:76,315,751–76,559,809, 3 genes, copy number 50: RN7SKP172, BBS10, OSBPL8.
- chr12:97,679,879–97,680,047, 1 gene, copy number 50: AC018659.2.
- chr12:101,836,820–101,873,623, 3 genes, copy number 51: RNA5SP369, RNU6-1183P, HSPE1P4.
- chr12:109,347,903–109,455,523, 1 gene, copy number 16 (within-gene range 4–16): MYO1H.
- chr12:109,445,410–109,598,125, 6 genes, copy number 16: AC007570.1, KCTD10, UBE3B, MMAB, RNU4-32P, MVK.
- chr12:109,833,348–109,999,127, 9 genes, copy number 54 (within-gene range 3–54): MIR4497, GLTP, AC007834.2, RN7SL441P, AC007834.1, TCHP, GIT2, AC084876.1, AC084876.2.
- chr12:112,013,348–112,509,918, 16 genes, copy number 17: ERP29, AC073575.2, NAA25, MIR3657, AC073575.1, Y_RNA, TRAFD1, Y_RNA, HECTD4, MIR6861, AC004217.1, RN7SKP71, RPL7AP60, AC004217.2, RPL6, PTPN11.
- chr12:118,645,315–118,738,511, 2 genes, copy number 16: LINC02460, RPL17P37.
- chr12:122,063,306–122,266,494, 9 genes, copy number 17: AC156455.1, MLXIP, LRRC43, IL31, B3GNT4, AC048338.2, DIABLO, AC048338.1, VPS33A.
- chr12:130,651,342–130,669,233, 1 gene, copy number 26 (within-gene range 5–46): AC095350.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
